CCDI case PBCICB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e5256026-c617-43db-b447-6e44db682285

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 6.1 years (2,215 days).

Biospecimens (3 samples)
- Sample 0DSG1Y: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSG25: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSG2M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
